Gene-level copy-number profile of tumor specimen ALCH-B1RI-TTP1-A from ALCHEMIST case ALCH-B1RI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.8 years (25,510 days).
Specimen ALCH-B1RI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f4187211-42b7-4c37-9d25-97cda3184a7a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/83b68dd2-4677-4186-ac30-02dcd916a1be

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 17,644; copy number 2: 38,771; copy number 3: 1,954; copy number 4: 7; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,558,025–50,672,048, 6 genes: C3orf18, HEMK1, AC096920.1, CISH, MAPKAPK3, LINC02019.
- chr3:50,675,080–50,685,791, 2 genes (within-gene range 0–1): MIR4787, PPIAP69.
- chr3:134,597,801–135,439,888, 6 genes (within-gene range 0–1): EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1.
- chr5:173,020,728–173,020,928, 1 gene (within-gene range 0–1): SNORA74B.
- chr7:73,339,094–73,339,200, 1 gene (within-gene range 0–2): RNU6-1080P.
- chr12:56,923,133–56,959,374, 3 genes: SDR9C7, AC026120.2, RDH16.
- chr20:37,602,852–37,603,185, 1 gene: GLRXP1.
- chr22:35,380,361–35,394,214, 1 gene: HMOX1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,583,731–105,588,395, 1 gene, copy number 5: IGHA2.

Autosomal genes at a single copy (total copy number 1): 17,643. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
